Somatic mutation profile of tumor specimen 0DSYEE from CCDI case PBCIGR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal sarcoma; Tissue or organ of origin: Liver; Age at diagnosis: 13.5 years (4,929 days).
Specimen 0DSYEE: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69529cd9-813c-4e78-9611-6046c0807e53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSYE7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62620418-a69d-4fe1-8e06-99564356cbf8

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 1, 3'UTR 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 221/282 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- DECR2 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs1282801082; called by muse, mutect2
- NF2 | c.1574+1G>C p.X525_splice | Splice Site (SNP) | VAF 320/401 reads (80%) | catalogued as CS077991, CS982293, CS982295, COSV58519686; called by muse, mutect2, varscan2
- NUP188 | c.3749G>A p.R1250H | Missense Mutation (SNP) | VAF 250/320 reads (78%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as rs754325591; called by muse, mutect2, varscan2
- OBSCN | c.17393C>T p.T5798M | Missense Mutation (SNP) | VAF 195/331 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs755362561; called by muse, mutect2, varscan2
- CDH23 | c.1492T>G p.F498V | Missense Mutation (SNP) | VAF 212/259 reads (82%) | SIFT tolerated (0.17); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- EEF1A2 | c.197A>C p.E66A | Missense Mutation (SNP) | VAF 43/469 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- MAP1B | c.7379C>T p.S2460F | Missense Mutation (SNP) | VAF 238/563 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RDH8 | c.460C>T p.Q154* (on ENST00000651512; = p.Q134* on NM_015725.4) | Nonsense Mutation (SNP) | VAF 259/332 reads (78%) | called by muse, mutect2, varscan2
- SLC35B1 | c.112A>G p.M38V (on ENST00000649906; = p.M1? on NM_005827.4) | Missense Mutation (SNP) | VAF 319/655 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TAF1L | c.1380G>C p.K460N | Missense Mutation (SNP) | VAF 311/377 reads (82%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XIRP2 | c.823G>A p.E275K (on ENST00000628543; = p.E450K on NM_152381.6) | Missense Mutation (SNP) | VAF 317/460 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACE | c.774C>T p.V258= | Silent (SNP) | VAF 169/536 reads (32%) | catalogued as COSV52003703; called by muse, mutect2, varscan2
- GPS1 | c.*36C>T | 3'UTR (SNP) | VAF 148/448 reads (33%) | called by muse, mutect2, varscan2
